FM case AD13758 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/00e7d8c4-095e-4881-8197-48d34c633e62

Male, 70.4 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the skin; metastasis. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
